Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20V, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20V-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

The patient is a 65-year-old woman with a large bladder tumor.

PRE-OP DIAGNOSIS: Bladder carcinoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Cystectomy, hysterectomy, and bilateral salpingo-oophorectomy.

FINAL DIAGNOSIS:

PART 1: RIGHT DISTAL URETERAL SHAVE MARGIN, BIOPSY -

- A. UROTHELIAL MUCOSA WITH FOCAL DYSPLASIA (see comment).
B. NO INVASIVE CARCINOMA SEEN.

* Selection Date:

B. NO INVASIVE CARCINOMA SEEN.

ICD-0-3

Carcinoma, urothelial 8/20/3

Site: bladder, lateral wall C67.2
lw 4/7/11

PART 2: LEFT DISTAL URETERAL SHAVE MARGIN, BIOPSY -
A. BENIGN SEGMENT OF SMALL INTESTINE

- A. BENIGN SEGMENT OF FALLOPIAN TUBE.
B. NO URETER PRESENT.
C. NO EVIDENCE OF MALIGNANCY.

B. NO URETER PRESENT.

C. NO EVIDENCE OF MALIGNANCY.

PART 3: FINAL URETHRAL MARGIN, BIOPSY -

- A. INVASIVE UROTHELIAL CARCINOMA, EXTENDING TO APPROXIMATELY 2 mm FROM THE URETHRAL RADIAL RESECTION MARGIN.
- B. FLAT UROTHELIAL CARCINOMA IN-SITU, EXTENDING TO LESS THAN 1 mm FROM THE URETHRAL RADIAL RESECTION MARGIN.

B. FLAT UROTHELIAL CARCINOMA IN-SITU, EXTENDING TO LESS THAN 1 mm FROM THE URETHRAL RADIAL RESECTION MARGIN.

PART 4: URINARY BLADDER, UTERUS, CERVIX, BILATERAL OVARIES AND BILATERAL FALLOPIAN TUBES, RADICAL CYSTECTOMY, HYSTERECTOMY, AND BILATERAL SALPINGO-OOPHORECTOMY -

URINARY BLADDER:

1. **INVASIVE UROTHELIAL CARCINOMA, HIGH-GRADE (2004 WHO/SUP), 5.0 CM, INVOLVING THE BLADDER NECK AND THE POSTERIOR, RIGHT LATERAL AND LEFT LATERAL WALLS OF THE BLADDER. CARCINOMA EXTENDS INTO THE RIGHT AND LEFT URETERAL ORIFICES (SLIDES 4B AND 4C).**
2. **UROTHELIAL CARCINOMA PENETRATES THROUGH THE DETRUSOR MUSCLE AND EXTENDS INTO THE PERIVESICAL ADIPOSE TISSUE (SLIDES 4G, 4H, AND 4J) AND INTO THE UTERUS (SLIDES 4L, 4W, 4X, 4Y, AND 4Z).**
3. **MULTIFOCAL LYMPHOVASCULAR INVASION IS IDENTIFIED (SLIDES 4B, 4X, 4Y, AND 4Z).**
4. **PERINEURAL INVASION IS IDENTIFIED (SLIDE 4J).**
5. **SURROUNDING BLADDER MUCOSA WITH MULTIFOCAL PAPILLARY UROTHELIAL CARCINOMA, FOCALLY HIGH-GRADE, INVOLVING THE POSTERIOR BLADDER WALL (SLIDES 4L AND 4M).**
6. **ALL FINAL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA, BUT INVASIVE CARCINOMA AND CARCINOMA IN-SITU ARE CLOSE TO THE FINAL URETHRAL MARGIN (see part 3).**
7. **TNM PATHOLOGIC STAGE: T4a N2 MX (see synoptic and part 5).**

2. UROTHELIAL CARCINOMA PENETRATES THROUGH THE DETRUSOR MUSCLE AND EXTENDS INTO THE PERIVESICAL ADIPOSE TISSUE (SLIDES 4G, 4H, AND 4J) AND INTO THE UTERUS (SLIDES 4L, 4W, 4X, 4Y, AND 4Z).

4. PERINEURAL INVASION IS IDENTIFIED (SLIDE 4Z)

4. PERINEURAL INVASION IS IDENTIFIED (SLIDE 4J).

5. SURROUNDING BLADDER MUCOSA WITH MULTIFOCAL PAPILLARY UROTHELIAL CARCINOMA, FOCALLY HIGH-GRADE, INVOLVING THE POSTERIOR BLADDER WALL (SLIDES 4L AND 4M).
6. ALL FINAL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.

6. ALL FINAL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA, BUT INVASIVE CARCINOMA AND CARCINOMA IN-SITU ARE CLOSE TO THE FINAL URETHRAL MARGINS.

7. **TNM PATHOLOGIC STAGE:** T4a N2 MX (see synoptic and part 5).

UTERUS, CERVIX, BILATERAL OVARIES, AND FALLOPIAN TUBES:

1. INVASIVE UROTHELIAL CARCINOMA EXTENSIVELY INVOLVING ECTOCERVIX AND ENDOCERVIX, MYOMETRIUM, AND ENDOMETRIUM.
2. FOCAL ENDOMETRIAL CYSTIC ATROPHY.
3. TWO LEIOMYOMAS, 1.5 AND 1.2 CM (SLIDES 4X AND 4Y).
4. BENIGN BILATERAL OVARIES WITH MULTIPLE CORPORA ALBICANTIA.
5. BENIGN BILATERAL FALLOPIAN TUBES.

2. FOCAL ENDOMETRIAL CYSTIC ATROPHY.

3. TWO LEIOMYOMAS, 1.5 AND 1.2 CM (SLIDES 4X AND 4Y).

4. BENIGN BILATERAL OVARIES WITH MULTIPLE CORPORA ALBICANTIA.

5. BENIGN BILATERAL FALLOPIAN TUBES.

PART 5: LYMPH NODES, RIGHT PELVIC, LYMPH NODE DISSECTION -

- A. METASTATIC CARCINOMA IN TWO OF THREE LYMPH NODES (2/3).
B. LARGEST METASTATIC FOCUS MEASURES 1.2 cm IN A HISTOLOGIC SECTION (SLIDE 5B).
C. FOCAL EXTRACAPSULAR EXTENSION IS NOTED (SLIDE 5C).

B. LARGEST METASTATIC FOCUS MEASURES ≤ 1 CM

C. FOCAL EXTRACAPSULAR EXTENSION IS NOTED (SLIDE 5C).

PART 6: LEFT DISTAL URETERAL SHAVE MARGIN, BIOPSY -

- A. MICROSCOPIC FOCUS OF DETACHED DYSPLASTIC UROTHELIUM IS PRESENT AT THE SHAVE URETERAL RESECTION MARGIN.**
- B. MICROSCOPIC FOCUS OF INVASIVE UROTHELIAL CARCINOMA IS PRESENT IN THE URETERAL MUSCULARIS PROPRIA AND PERIURETERAL SOFT TISSUE CLOSE TO BUT NOT INVOLVING THE ACTUAL URETERAL RESECTION MARGIN (see comment).**

B. MICROSCOPIC FOCUS OF INVASIVE UROTHELIAL CARCINOMA IS PRESENT IN THE URETERAL MUSCULARIS PROPRIA AND PERIURETERAL SOFT TISSUE CLOSE TO BUT NOT INVOLVING THE ACTUAL URETERAL RESECTION MARGIN (see comment).

COMMENT:

Part 1 (right distal ureteral margin): The focus of urothelial dysplasia is represented only on the original frozen section slides. On the permanent section, the ureter is represented as a complete cross-section with no dysplasia represented.

Part 6 (left distal ureteral margin): On the original frozen section slides, there was a small detached fragment of dysplastic urothelium, with no invasive urothelial carcinoma present. However, on the permanent sections representing deeper levels into the tissue, small foci of invasive urothelial carcinoma are present in the muscularis propria of the ureter and within the periureteral soft tissue. Therefore, invasive carcinoma is close to the true margin and detached dysplastic urothelium is at the true margin.

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS****SPECIMEN TYPE:**

Radical cystectomy

TUMOR SITE:

Right lateral wall, Left lateral wall, Anterior wall, Posterior wall

TUMOR SIZE:

Greatest dimension: 5.0 cm

Additional dimensions: 4.2 X 2.2 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma

ASSOCIATED EPITHELIAL LESIONS:

None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Papillary, Solid/nodule, Ulcerated

PATHOLOGIC STAGING (pTNM):

pT4a

pN2

Number of nodes examined: 3

Number of nodes involved: 2

pMX

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 1 mm

Margin: left ureter (see comment)

Margin(s) uninvolved by carcinoma in situ

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Present

DIRECT EXTENSION OF INVASIVE TUMOR:

Perivesical fat

Uterus and adnexae

Ureter: Right and left

ADDITIONAL PATHOLOGIC FINDINGS:

Urothelial dysplasia (low-grade intraurothelial neoplasia)

Inflammation/regenerative changes

Other: Carcinoma in situ

Comment:

There is a microscopic detached fragment of dysplastic urothelium at the left ureteral resection margin.

Source: NCI Genomic Data Commons file e6143187-91bf-4b26-ac4a-09c19f0787f6 (TCGA-BT-A20V.9D40A90D-AD9C-4754-A65C-799C23183534.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).